TCGA case TCGA-12-0827 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b75845ed-a19a-4caa-b362-e62b1e538152

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 38 years; Vital status: Dead; Days to death: 1,179 days (3.2 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 38.6 years (14,093 days); Year of diagnosis: 1999; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Monoclonal Antibody 81C6; Treatment intent type: Adjuvant; Days to treatment start: 34 days; Days to treatment end: 76 days; Treatment dose: 20 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Days to treatment start: 34 days; Days to treatment end: 76 days; Treatment dose: 120 mCi.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 76 days; Days to treatment end: 127 days; Treatment dose: 5,940 cGy; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 137 days; Days to treatment end: 181 days; Number of cycles: 1; Treatment dose: 110 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 181 days; Days to treatment end: 258 days; Number of cycles: 1; Treatment dose: 83 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 258 days; Days to treatment end: 350 days; Number of cycles: 1; Treatment dose: 150 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 350 days; Days to treatment end: 390 days (1.1 years); Number of cycles: 1; Treatment dose: 200 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 390 days (1.1 years); Days to treatment end: 434 days (1.2 years); Number of cycles: 1; Treatment dose: 410 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 466 days (1.3 years); Days to treatment end: 615 days (1.7 years); Number of cycles: 4; Treatment dose: 200 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 615 days (1.7 years); Days to treatment end: 746 days (2.0 years); Treatment dose: 160 mg; Route of administration: Oral.
2. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tumor of origin: diagnosis 1 of this record; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 452 days (1.2 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,179 days (3.2 years); Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Post Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-0827-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-12-0827-01A-01-BS1: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 50; Percent lymphocyte infiltration: 0.
  Slide TCGA-12-0827-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0.
- Sample TCGA-12-0827-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-0827-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 3: Pharmaceutical therapy drug name: 81C6.
- Drug treatment 4: Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 5: Pharmaceutical therapy drug name: CPT-11.
- Drug treatment 5, Route of administrations: Route of administration: IV.
- Drug treatment 6: Pharmaceutical therapy drug name: MABI131.
- Follow-up form, New tumor event: New tumor event type: Locoregional Disease; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,179 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,179 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,179 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-0827-01A-01D-0384-01): tumor purity 0.58, ploidy 1.8, whole-genome doublings 0.
